TCGA case TCGA-85-8352 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/159b96ab-2eb9-4604-be8c-e38f6aae103f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 67 years; Vital status: Dead; Days to death: 161 days.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.9 years (24,788 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 161 days; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 68.2 years (24,916 days); Days to diagnosis: 128 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 67 days; Disease response: Tumor Free.
- Day 128 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 128 days.
- Days to follow up: 161 days; Disease response: With Tumor.
- Karnofsky performance status: 80.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 50; Tobacco smoking onset year: 1962.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-85-8352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-85-8352-01A-02-BS2: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 0.
- Sample TCGA-85-8352-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-85-8352-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; Pulmonary function test indicator: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 161 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 161 days; disease-free interval: event (new tumor event after initially disease-free), 128 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 128 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-85-8352-01A-31D-2322-01): tumor purity 0.93, ploidy 2.9, whole-genome doublings 1.
